Somatic mutation profile of tumor specimen MP2PRT-PAVGAZ-TMP1-A (aliquot MP2PRT-PAVGAZ-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVGAZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,373 days).
Specimen MP2PRT-PAVGAZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e65687bc-facc-40f7-8c58-2b501ce66bf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVGAZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVGAZ-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98f6c8d2-2473-4f68-af14-c375ebec65ce

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCED1B | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 55/539 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.844); catalogued as rs754473510, COSV71395257; called by muse, mutect2, varscan2
- PPFIA2 | c.2987C>T p.T996M | Missense Mutation (SNP) | VAF 108/291 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs1255897628; called by muse, mutect2, varscan2
- AKAP6 | c.5056G>A p.A1686T | Missense Mutation (SNP) | VAF 33/514 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- PLEC | c.11821C>A p.L3941M (on ENST00000322810 / NM_201380.4; = p.L3831M on NM_000445.5) | Missense Mutation (SNP) | VAF 176/632 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- THAP3 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 68/525 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406871 TTCAC>G | Silent (DEL) | VAF 65/189 reads (34%) | called by pindel, varscan2*
- SLC26A9 | c.63C>T p.D21= | Silent (SNP) | VAF 32/484 reads (7%) | catalogued as rs1466205950, COSV61604817; called by muse, mutect2
